Somatic mutation profile of tumor specimen TARGET-30-PAUTKP-01A (aliquot TARGET-30-PAUTKP-01A-01D) from TARGET case TARGET-30-PAUTKP, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.7 years (609 days).
Specimen TARGET-30-PAUTKP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77ba3bff-e4cf-4a0a-9f71-1bc31bd557c4.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUTKP-10A (Blood Derived Normal), aliquot TARGET-30-PAUTKP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b7aeee7-e8a6-4005-b962-f56ce81aa6be

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 15/50 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113994087, CM085230, COSV66555567, COSV66558183; ClinVar: pathogenic / likely pathogenic /  risk factor; called by muse, mutect2, varscan2
